TCGA case TCGA-EM-A2CS — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: University Health Network. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7555e736-a9e2-4b96-a633-fb0f7224d62c

Demographics
Sex at birth: female; Country of residence at enrollment: Canada; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Papillary carcinoma, oxyphilic cell: ICD-O-3 morphology code: 8342/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 52.0 years (18,990 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1b; AJCC pathologic M: MX; AJCC pathologic stage: Stage IVA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 841 days (2.3 years); Tumor focality: Multifocal.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 35; Lymph nodes tested: 49; Measurement unit: Centimeters; Tumor depth measurement: 1.3; Tumor length measurement: 6.3; Tumor width measurement: 3.6.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 91 days; Days to treatment end: 91 days; Treatment dose: 150 mCi; Treatment outcome: Partial Response; Number of fractions: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 497 days (1.4 years); Days to treatment end: 542 days (1.5 years); Treatment dose: 66 Gy; Treatment outcome: Partial Response; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Prescribed dose: 150; Pretreatment: Thyroxine Withdrawal; Timepoint category: First Treatment.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Treatment dose: 150; Pretreatment: Thyroxine Withdrawal.
   Treatment given: Treatment type: Radiation, Intensity-Modulated Radiotherapy; Treatment intent type: Adjuvant; Prescribed dose: 66; Radiosensitizing agent: No.
   Treatment given: Treatment type: Radiation, Intensity-Modulated Radiotherapy; Treatment intent type: Adjuvant; Prescribed dose: 66.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (5 entries)
- Days to follow up: 313 days; Disease response: With Tumor.
- Days to follow up: 491 days (1.3 years); Disease response: With Tumor.
- Days to follow up: 841 days (2.3 years); Disease response: With Tumor.
- Disease response: Persistent Locoregional Disease; Timepoint: Within 3 Months of Surgery.
- Imaging type: CT Scan; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Thyroid Cancer.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EM-A2CS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 130 mg.
  Slide TCGA-EM-A2CS-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-EM-A2CS-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EM-A2CS-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Initial weight: 100 mg.
  Slide TCGA-EM-A2CS-06A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-EM-A2CS-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Classical/usual; Laterality: Right lobe; Lymph nodes preop imaging: Yes; Lymph nodes examined: Yes; Genotypic analysis detected: No.
- Lymph node preoperative assessment diagnostic imaging types: Lymph nodes preop imaging type: CT with contrast.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Radiation therapy xrt method prep: Imrt; Clinical status within 3 mths surgery: Persistent locoregional disease; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; Radiation therapy xrt method prep: Imrt; Radiation therapy xrt sensitizers: No; New tumor event diagnosis indicator: No.

GDC annotations on this case (curator notes; quoted as recorded):
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-EM-A2CS-01A-11D-A17R-02: DNA aliquot UUID: 7129B89B-A326-40D1-9E8E-F18A6C76EE9B contains a sample that does not match the genotype for this patient. It has been replaced by DNA UUID: 9ABC3C93-71E6-463A-AAB3-DA03676907E1.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-EM-A2CS-01A-11D-A17S-01: DNA aliquot UUID: 183679E3-91B5-4188-B5C4-D0ACB15ABB8A contains a sample that does not match the genotype for this patient. It has been replaced by DNA UUID: 1E574008-13A2-4E0C-8F77-D2E3D73D6662.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-EM-A2CS-01A-11D-A17V-08: DNA aliquot UUID: 032AC4DF-2B53-476D-965A-691D16A7BAA5 contains a sample that does not match the genotype for this patient. It has been replaced by DNA UUID: 55AB2585-C937-4A29-9CAF-62DAF8FCCC5D.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-EM-A2CS-01A-11D-A17Y-05: DNA aliquot UUID: 491AFBCB-D439-469C-9781-82F0707E997C contains a sample that does not match the genotype for this patient. It has been replaced by DNA UUID: 06471EC4-E769-48FC-BB41-963C7B9A50D3.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-EM-A2CS-06A-11D-A17R-02: DNA aliquot UUID: 12FCE346-22F5-4E77-A5FF-06A2A9F96B07 contains a sample that does not match the genotype for this patient. It has been replaced by DNA UUID: 5F6DED47-5C5F-4154-B030-E08ECF2ED005.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-EM-A2CS-06A-11D-A17S-01: DNA aliquot UUID: C84B793A-957C-48AE-9EF9-9FC3DBAF33A2 contains a sample that does not match the genotype for this patient. It has been replaced by DNA UUID: 1E799591-6697-4C1C-8289-AF911B46DF3A.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-EM-A2CS-06A-11D-A17V-08: DNA aliquot UUID: E8211671-BD48-4956-B6EC-F74AB2512A50 contains a sample that does not match the genotype for this patient. It has been replaced by DNA UUID: 46EFE84B-E856-4B4D-A1FA-578578741495.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-EM-A2CS-06A-11D-A17Y-05: DNA aliquot UUID: 445C9A9F-C83B-4A81-9E59-FDAF84F869E0 contains a sample that does not match the genotype for this patient. It has been replaced by DNA UUID: 4D1A9CA1-D441-430F-B9CD-B20D632428F0.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-EM-A2CS-10A-01D-A17R-02: DNA aliquot UUID: C8598CE0-36E7-4157-9E76-1BCC2389151F contains a sample that does not match the genotype for this patient. It has been replaced by DNA UUID: EC6A8027-E14A-4592-BF7D-8F7E1232FE69.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-EM-A2CS-10A-01D-A17S-01: DNA aliquot UUID: 59D4770F-1D12-4028-A728-237040C3E356 contains a sample that does not match the genotype for this patient. It has been replaced by DNA UUID: 5F37673A-1B44-44B1-B4B0-BC9DBA62B875.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-EM-A2CS-10A-01D-A17V-08: DNA aliquot UUID: 227AE7C1-FE1E-49AF-A126-37868D272453 contains a sample that does not match the genotype for this patient. It has been replaced by DNA UUID: 6A6FD1E9-9604-4D58-A7A7-3CE60B565972.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 841 days; disease-specific survival: no event (censored), 841 days; progression-free interval: no event (censored), 841 days.
